Somatic mutation profile of cancer-model specimen HCM-CSHL-0192-C25-85A (3D Organoid; aliquot HCM-CSHL-0192-C25-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-CSHL-0192-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 67.7 years (24,739 days).
Specimen HCM-CSHL-0192-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5827ff6c-904f-4b58-aaa4-2d83ca26190e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0192-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0192-C25-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b2f0f55-b147-4fe4-8b58-843593970966

The open-access MAF lists 50 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 31, Silent 12, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 90/200 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 310/310 reads (100%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as rs371524413, CM984589, COSV52698013, COSV52700732, COSV52710835, COSV52891661; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADORA1 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 30/710 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV55141656; called by muse, mutect2
- BRCC3 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 252/252 reads (100%) | catalogued as rs782566613, COSV57464580; called by muse, mutect2, varscan2
- CARNS1 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 733/781 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs762936950; called by muse, mutect2, varscan2
- CDH10 | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 106/272 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs763581492, COSV52589090, COSV52594161; called by muse, varscan2
- CDH23 | c.5116C>T p.R1706C | Missense Mutation (SNP) | VAF 128/372 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs759876454, COSV99819982; called by muse, mutect2, varscan2
- COL6A2 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 40/478 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201792591, COSV100154215, COSV56015166; ClinVar: uncertain significance; called by muse, mutect2
- FLG | c.9517G>A p.D3173N | Missense Mutation (SNP) | VAF 45/582 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs577488038; called by muse, mutect2
- LRP3 | c.1789C>T p.R597W | Missense Mutation (SNP) | VAF 414/886 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs888271095; called by muse, mutect2, varscan2
- MYNN | c.1429G>A p.G477R | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV62991580; called by muse, mutect2, varscan2
- NPR3 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 107/294 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775585104, COSV54093751; called by muse, mutect2, varscan2
- NUDT16 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 112/315 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1214148554, COSV100720814, COSV63248311; called by muse, mutect2, varscan2
- PCDHGA4 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 384/834 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs375047889; called by muse, mutect2, varscan2
- PDZD7 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 285/575 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776680703, COSV100931710; called by muse, mutect2, varscan2
- RASGRF2 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 123/277 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1329580753, COSV54126312; called by muse, mutect2, varscan2
- SRRM4 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 36/604 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as rs114691929; called by muse, mutect2
- TTBK1 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 271/653 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs778738848, COSV52489206; called by muse, mutect2, varscan2
- UNC5D | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 154/365 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs775726745, COSV54776450; called by muse, mutect2, varscan2
- ZNF648 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 396/950 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as rs533801633, COSV100374421; called by muse, mutect2, varscan2
- CDKN2A | c.110_141del p.L37Pfs*72 | Frame Shift Del (DEL) | VAF 206/228 reads (90%) | called by mutect2, pindel, varscan2
- CNGB3 | c.967T>G p.F323V | Missense Mutation (SNP) | VAF 75/141 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CREBBP | c.6107C>A p.P2036H | Missense Mutation (SNP) | VAF 369/735 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- CTDSPL | c.405A>C p.E135D (on ENST00000273179 / NM_001008392.2; = p.E124D on NM_005808.3) | Missense Mutation (SNP) | VAF 96/171 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DSCAML1 | c.4324+1G>A p.X1442_splice (on ENST00000321322; = p.X1382_splice on NM_020693.4) | Splice Site (SNP) | VAF 35/233 reads (15%) | called by muse, mutect2, varscan2
- DUSP14 | c.549C>A p.D183E | Missense Mutation (SNP) | VAF 295/834 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- G3BP1 | c.808A>C p.I270L | Missense Mutation (SNP) | VAF 12/223 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2
- GGTLC1 | c.74A>T p.Y25F | Missense Mutation (SNP) | VAF 353/700 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H1-4 | c.137A>G p.K46R | Missense Mutation (SNP) | VAF 280/575 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- KMT2B | c.4250T>A p.L1417H | Missense Mutation (SNP) | VAF 469/943 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LYAR | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 40/543 reads (7%) | called by muse, mutect2
- MCM3 | c.1224G>T p.M408I (on ENST00000229854 / NM_001366374.2; = p.M398I on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- N4BP2L1 | c.75_77del p.P26del | In Frame Del (DEL) | VAF 230/638 reads (36%) | called by pindel, varscan2
- PALLD | c.2164A>G p.N722D | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2
- SMAD4 | c.452dup p.N151Kfs*11 | Frame Shift Ins (INS) | VAF 52/87 reads (60%) | called by mutect2, pindel, varscan2
- THAP11 | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 189/378 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ZFP36L2 | c.921del p.S308Rfs*153 | Frame Shift Del (DEL) | VAF 384/926 reads (41%) | called by mutect2, pindel, varscan2
- ZNF611 | c.2000G>A p.R667K | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARAP1 | c.126C>T p.S42= | Silent (SNP) | VAF 717/842 reads (85%) | catalogued as rs376463871; called by muse, mutect2, varscan2
- CTSG | c.660G>A p.S220= | Silent (SNP) | VAF 155/294 reads (53%) | catalogued as rs757296409, COSV53536044; called by muse, mutect2, varscan2
- FAM135B | c.1665C>T p.D555= | Silent (SNP) | VAF 135/321 reads (42%) | catalogued as rs757138084, COSV52753154; called by muse, mutect2, varscan2
- FOXN1 | c.1605A>G p.S535= | Silent (SNP) | VAF 208/415 reads (50%) | called by muse, mutect2, varscan2
- HOXD3 | c.1152G>A p.S384= | Silent (SNP) | VAF 96/992 reads (10%) | called by muse, mutect2
- ITGAL | c.123C>T p.A41= | Silent (SNP) | VAF 262/526 reads (50%) | catalogued as rs754606863; called by muse, mutect2, varscan2
- MYO16 | c.4965G>A p.S1655= | Silent (SNP) | VAF 278/912 reads (30%) | catalogued as COSV62746562; called by muse, varscan2
- NPHP4 | c.2346C>T p.H782= | Silent (SNP) | VAF 252/554 reads (45%) | catalogued as rs1433852047, CM051578, COSV100977128; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR1S2 | c.363C>T p.V121= | Silent (SNP) | VAF 246/294 reads (84%) | catalogued as rs201099062; called by muse, mutect2, varscan2
- PCDHGA1 | c.2106C>T p.C702= | Silent (SNP) | VAF 482/965 reads (50%) | catalogued as rs752862628, COSV65295884; called by muse, mutect2, varscan2
- STIM2 | c.75G>A p.R25= | Silent (SNP) | VAF 370/724 reads (51%) | called by muse, mutect2, varscan2
- TRPC7 | c.660C>T p.N220= | Silent (SNP) | VAF 207/468 reads (44%) | catalogued as COSV61452104; called by muse, mutect2, varscan2
